CCDI case PBBISY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/c0d9cf5e-d001-4249-b08b-a5ca5256ef6c

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.0 years (4,392 days).

Biospecimens (3 samples)
- Sample 0D9S2W: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0D9S3B: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0D9S43: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
